Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A70W, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A70W-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology [OrderID: _____]	Final Results
-------------------------------------	---------------

Final

Surgical Pathology

CASE NUMBER:

DIAGNOSIS: Adrenal, right (adrenalectomy): Pheochromocytoma, see Note.

NOTE: Inked margins appear free of tumor.

CLINICAL INFORMATION: Brief Clinical History: pheochromocytoma Specimen Taken For Protocol:
01 - Yes Allocate Order to Protocol: 1

PROCEDURE: Post-Operative Diagnosis: pheochromocytoma Operative Findings: right adrenal pheochromocytoma. Pre-Operative Diagnosis: pheochromocytoma

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, RIGHT

GROSS DESCRIPTION: Received fresh from O.R. labeled "right adrenal" is an adrenal mass with surrounding adipose tissue measuring 15 x 5 x 3 cm (75.45 grams). There is a nodule within the tissue measuring 3.5 x 3 cm. The lesional and perilesional tissue are inked in black. On sectioning, the tumor has a hemorrhagic and friable cut surface. Normal adrenal gland is present on the periphery. Approximately 50% of the tumor and normal ring of adrenal is procured for I

Normal adrenal (0.1%) is procured for the The procurement is carried out by at approximately The remainder of the specimen is placed in formalin for surgical pathology. At Surgical Pathology, the specimen received matched the above description. The specimen is further sectioned and the nodule is estimated to be 3 cm in thickness. The specimen is submitted in the designated white cassette labeled as as follows (the remaining tumor is entirely submitted):

A-I: Sections of the remaining tumor

J: Representative section of grossly normal adrenal cortex.

K-M: Sections of the remaining tumor.

Gross description dictated by

No consultants

#

[page 2 of 2]
Surgical Pathology (

Final Results

#

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Do not file in Medical Record

Requested By:

Source: NCI Genomic Data Commons file d635ca26-4d9c-4694-9559-1bd7ac00fc9b (TCGA-QR-A70W.8844D985-C14D-41E1-B7A0-9031D3A5B4EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).